CCDI case PBCDBD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a51b331f-c9a1-4ed7-9c2a-d594e67d8bd5

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.5 years (4,924 days).

Biospecimens (3 samples)
- Sample 0DP2CG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP2CK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DP2CX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
